Somatic mutation profile of tumor specimen ALCH-B0EU-TTP1-A (aliquot ALCH-B0EU-TTP1-A-1-0-D-A709-36) from ALCHEMIST case ALCH-B0EU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.0 years (25,556 days).
Specimen ALCH-B0EU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 727d3c0e-27b9-42d8-a3c3-52042025e22b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0EU-NB1-A (Blood Derived Normal), aliquot ALCH-B0EU-NB1-A-1-0-D-A709-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c4f6c6f-77f5-426f-a7a9-40bcb30c5b6a

The open-access MAF lists 214 somatic variants for this specimen: 136 protein-altering or splice-affecting, 49 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 49, Nonsense Mutation 13, Intron 12, 3'UTR 6, RNA 5, Frame Shift Del 3, 3'Flank 2, 5'Flank 2, 5'UTR 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>T p.G509V (on ENST00000288602 / NM_001374244.1; = p.G469V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 95/573 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 80/418 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADH7 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV99265446; called by muse, mutect2
- ARFGEF3 | c.5642G>T p.R1881L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV52462379; called by muse, mutect2, varscan2
- ATRX | c.4738A>T p.K1580* | Nonsense Mutation (SNP) | VAF 66/274 reads (24%) | catalogued as COSV64883872; called by muse, mutect2, varscan2
- CNOT10 | c.520G>T p.V174F | Missense Mutation (SNP) | VAF 21/332 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.23); catalogued as COSV100095263; called by muse, mutect2
- DGAT2 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as COSV57176328; called by muse, mutect2
- DIP2C | c.1477G>C p.D493H | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); catalogued as COSV55158617; called by muse, mutect2
- ESRP1 | c.573G>T p.M191I | Missense Mutation (SNP) | VAF 12/287 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1376669044, COSV64410456; called by muse, mutect2
- EYS | c.3677G>C p.G1226A | Missense Mutation (SNP) | VAF 12/301 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV58196845; called by muse, mutect2
- FAM151B | c.419G>C p.G140A | Missense Mutation (SNP) | VAF 21/416 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.19); catalogued as COSV56475084; called by muse, mutect2
- FANCD2 | c.1298C>A p.S433* | Nonsense Mutation (SNP) | VAF 20/740 reads (3%) | catalogued as COSV55045270; called by muse, mutect2
- FDXR | c.686G>T p.R229L (on ENST00000293195 / NM_024417.5; = p.R235L on NM_004110.6) | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1037312154; called by muse, mutect2
- GALNT13 | c.383G>C p.W128S | Missense Mutation (SNP) | VAF 23/232 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67239888; called by muse, mutect2, varscan2
- IGHV5-51 | c.240C>A p.S80R | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs533007610; called by muse, mutect2
- KIF22 | c.1208G>C p.R403P | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as COSV50717771; called by muse, mutect2, varscan2
- KLHL4 | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as rs1227509457, COSV100909198; called by muse, mutect2, varscan2
- LAMA4 | c.1582G>A p.E528K (on ENST00000230538 / NM_001105206.3; = p.E521K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/484 reads (4%) | SIFT tolerated (0.68); PolyPhen benign (0.127); catalogued as rs782385471, COSV100038155; ClinVar: uncertain significance; called by muse, mutect2
- LRP1 | c.2531C>T p.A844V | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs532661685, COSV54514895; called by muse, mutect2, varscan2
- MACC1 | c.241A>G p.I81V | Missense Mutation (SNP) | VAF 51/317 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs369411460; called by muse, mutect2, varscan2
- MAPKBP1 | c.4261C>A p.Q1421K (on ENST00000456763 / NM_001128608.2; = p.Q1415K on NM_014994.3) | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs767116803; called by mutect2, varscan2
- MEI1 | c.3292C>T p.R1098* | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | catalogued as rs372447858; called by muse, mutect2
- MUC16 | c.23258G>C p.R7753T | Missense Mutation (SNP) | VAF 44/293 reads (15%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); catalogued as COSV67488430; called by muse, mutect2, varscan2
- MYH2 | c.1254G>C p.Q418H | Missense Mutation (SNP) | VAF 23/537 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55433715; called by muse, mutect2
- MYH8 | c.572C>A p.T191N | Missense Mutation (SNP) | VAF 85/450 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1339759887; called by muse, mutect2, varscan2
- NCAPG2 | c.1656G>T p.R552S | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99317454; called by muse, mutect2, varscan2
- NPAP1 | c.1975G>C p.A659P | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.84); catalogued as rs778921793, COSV61506458; called by muse, mutect2, varscan2
- NPAS3 | c.821G>A p.R274H (on ENST00000356141 / NM_001164749.2; = p.R242H on NM_022123.3) | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60823133; called by muse, mutect2
- NPAS3 | c.2459C>T p.A820V (on ENST00000356141 / NM_001164749.2; = p.A788V on NM_022123.3) | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.163); catalogued as COSV60832129; called by muse, mutect2
- NPFFR2 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.428); catalogued as COSV100440464; called by muse, mutect2, varscan2
- OSTM1 | c.392G>C p.R131P | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV51970300; called by muse, mutect2
- POLD1 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70956619; called by muse, mutect2, varscan2
- PZP | c.2849C>T p.A950V | Missense Mutation (SNP) | VAF 36/314 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as rs1032966506; called by muse, mutect2, varscan2
- RABGGTA | c.1209G>C p.E403D | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99253278; called by muse, mutect2
- RASSF8 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 11/116 reads (9%) | catalogued as rs1410077079, COSV51452798; called by muse, mutect2, varscan2
- ROS1 | c.2506C>G p.L836V | Missense Mutation (SNP) | VAF 20/310 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV63861050; called by muse, mutect2
- RTL9 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.273); catalogued as COSV71826110; called by muse, mutect2, varscan2
- SDC1 | c.103G>C p.D35H | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54341612; called by muse, mutect2
- SDSL | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs147923357; called by muse, mutect2, varscan2
- SENP1 | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50302749; called by muse, mutect2
- SPATA17 | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV65119601; called by muse, mutect2, varscan2
- SSC5D | c.2756C>T p.S919F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs951616893; called by muse, mutect2, varscan2
- TFAP2B | c.994C>A p.P332T | Missense Mutation (SNP) | VAF 32/423 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53830531; called by muse, mutect2
- TFB1M | c.993C>G p.S331R | Missense Mutation (SNP) | VAF 34/404 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV51644024; called by muse, mutect2
- TRPA1 | c.2911G>T p.A971S | Missense Mutation (SNP) | VAF 66/493 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100084852; called by muse, mutect2, varscan2
- UBR4 | c.7387G>T p.D2463Y | Missense Mutation (SNP) | VAF 17/278 reads (6%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.673); catalogued as COSV100920676; called by muse, mutect2
- UTRN | c.2442C>G p.I814M | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs1253305916, COSV62330526; called by muse, mutect2
- UTRN | c.9599G>A p.R3200Q | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs962310762; called by muse, mutect2
- WWP2 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.038); catalogued as rs1473094766, COSV100598592, COSV63124040; called by muse, mutect2, varscan2
- ZNF215 | c.171G>T p.L57F | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV53492612, COSV53493684; called by muse, mutect2, varscan2
- ZNF727 | c.61C>A p.L21M | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71646849; called by muse, mutect2, varscan2
- AATF | c.1578C>A p.F526L | Missense Mutation (SNP) | VAF 20/390 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- ADRA1B | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ARHGEF40 | c.4306G>T p.G1436C | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ATIC | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2
- CACNA1E | c.1253G>T p.S418I | Missense Mutation (SNP) | VAF 17/280 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.205); called by muse, mutect2
- CACNA2D1 | c.1295G>A p.R432K | Missense Mutation (SNP) | VAF 38/520 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- COL11A1 | c.1700A>T p.Q567L | Missense Mutation (SNP) | VAF 60/345 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- COL6A5 | c.5018C>T p.P1673L | Missense Mutation (SNP) | VAF 14/417 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); called by muse, mutect2
- CRTC2 | c.372+2T>C p.X124_splice | Splice Site (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- CRYGB | c.5del p.G2Efs*43 | Frame Shift Del (DEL) | VAF 29/295 reads (10%) | called by mutect2, pindel, varscan2
- DLL1 | c.1389C>A p.N463K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- DMXL1 | c.2672C>T p.S891L | Missense Mutation (SNP) | VAF 32/544 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.231); called by muse, mutect2
- DNAH14 | c.7674A>T p.K2558N (on ENST00000445597; = p.K3330N on NM_001367479.1) | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.627); called by muse, mutect2
- EDA | c.667C>G p.P223A | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ENTPD6 | c.1075A>T p.R359* | Nonsense Mutation (SNP) | VAF 20/138 reads (14%) | called by muse, mutect2, varscan2
- EP300 | c.1808G>A p.R603K | Missense Mutation (SNP) | VAF 40/452 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.809); called by muse, mutect2
- EPHA8 | c.869G>T p.C290F | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2
- FAM205A | c.2573C>A p.P858H | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by mutect2, varscan2
- FCGBP | c.4475G>C p.C1492S | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- G3BP2 | c.247C>A p.H83N | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2
- GALNT3 | c.913G>C p.D305H | Missense Mutation (SNP) | VAF 31/626 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); called by muse, mutect2
- GRK7 | c.951G>A p.M317I | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.326); called by muse, mutect2
- GRM7 | c.1381G>T p.A461S | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.138); called by muse, mutect2
- HMCN2 | c.14447C>A p.P4816H | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); called by muse, mutect2
- ICE1 | c.1270G>T p.E424* | Nonsense Mutation (SNP) | VAF 11/215 reads (5%) | called by muse, mutect2
- IGHV5-51 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 28/356 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.14); called by muse, mutect2
- INF2 | c.2340C>G p.F780L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KAT6A | c.2328G>T p.W776C | Missense Mutation (SNP) | VAF 64/730 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KCNB2 | c.389A>T p.E130V | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- KCTD3 | c.675G>T p.L225F | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- KDR | c.932G>A p.S311N | Missense Mutation (SNP) | VAF 21/264 reads (8%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.982); called by muse, mutect2
- KIF3C | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 12/223 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KPTN | c.789G>C p.E263D | Missense Mutation (SNP) | VAF 15/195 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- KRT74 | c.284del p.G95Afs*53 | Frame Shift Del (DEL) | VAF 18/142 reads (13%) | called by mutect2, pindel, varscan2
- LYPD3 | c.190G>T p.A64S | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.053); called by muse, mutect2
- MAGEB18 | c.679G>A p.G227S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ME1 | c.556C>G p.Q186E | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.005); called by muse, mutect2
- MELK | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 42/225 reads (19%) | called by muse, mutect2, varscan2
- MINAR1 | c.1918G>C p.V640L | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MINAR2 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 14/457 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2
- MS4A2 | c.269del p.G90Efs*38 | Frame Shift Del (DEL) | VAF 42/463 reads (9%) | called by pindel, varscan2
- NBEAL1 | c.973C>G p.L325V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, varscan2
- NBPF15 | c.1901C>T p.S634L | Missense Mutation (SNP) | VAF 28/554 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.071); called by muse, mutect2
- NR0B1 | c.1067C>A p.S356Y | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- NRXN1 | c.2282G>C p.R761T | Missense Mutation (SNP) | VAF 16/376 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.325); called by muse, mutect2
- OR11L1 | c.671C>A p.S224Y | Missense Mutation (SNP) | VAF 23/472 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2
- OR4C15 | c.922A>G p.I308V (on ENST00000314644; = p.I254V on NM_001001920.2) | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR8B12 | c.698G>T p.R233M | Missense Mutation (SNP) | VAF 30/396 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.171); called by muse, mutect2
- P2RX6 | c.325G>T p.V109L | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PDE7A | c.290C>G p.S97C (on ENST00000401827 / NM_001242318.3; = p.S71C on NM_002603.4) | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.497); called by muse, mutect2
- PDZD11 | c.124C>G p.Q42E | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PGM2L1 | c.384G>C p.Q128H | Missense Mutation (SNP) | VAF 20/253 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- PIGN | c.2471C>G p.P824R | Missense Mutation (SNP) | VAF 30/390 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- POLQ | c.4240A>T p.S1414C | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- PPP2R5C | c.398A>T p.H133L | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKDC | c.5125G>T p.E1709* | Nonsense Mutation (SNP) | VAF 21/178 reads (12%) | called by muse, mutect2, varscan2
- PTPRH | c.2615C>A p.S872Y | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- RAB5A | c.643A>C p.N215H | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.076); called by muse, mutect2
- RCL1 | c.831G>C p.R277S | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.014); called by muse, varscan2
- SCN7A | c.2377C>A p.H793N | Missense Mutation (SNP) | VAF 50/382 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC3A1 | c.153C>G p.I51M | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); called by muse, mutect2
- SMYD4 | c.1414C>G p.Q472E | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2
- SNRPB | c.676G>T p.G226W | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SURF2 | c.146G>C p.G49A | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE2 | c.3715C>A p.L1239M | Missense Mutation (SNP) | VAF 24/528 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); called by muse, mutect2
- TAF7 | c.543G>T p.W181C | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- TDO2 | c.1106C>G p.S369* | Nonsense Mutation (SNP) | VAF 13/290 reads (4%) | called by muse, mutect2
- TENT4A | c.1741C>T p.Q581* | Nonsense Mutation (SNP) | VAF 26/130 reads (20%) | called by muse, mutect2, varscan2
- THBS2 | c.1022G>T p.C341F | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIPRL | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 24/261 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- TLN1 | c.2096A>C p.Q699P | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TMEM43 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 16/148 reads (11%) | called by muse, mutect2, varscan2
- TPH1 | c.1282C>G p.L428V | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.974); called by muse, mutect2
- TTLL2 | c.1591C>A p.H531N | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.031); called by muse, mutect2
- UBE2K | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); called by muse, mutect2
- UBE2L6 | c.408C>G p.F136L | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); called by muse, mutect2
- VPS13B | c.7000C>G p.P2334A | Missense Mutation (SNP) | VAF 56/702 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2
- ZIC2 | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 22/160 reads (14%) | called by muse, mutect2, varscan2
- ZKSCAN2 | c.1846C>G p.P616A | Missense Mutation (SNP) | VAF 9/236 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.055); called by muse, mutect2
- ZNF101 | c.408G>T p.W136C | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- ZNF257 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 7/153 reads (5%) | called by muse, mutect2
- ZNF292 | c.5088G>T p.Q1696H | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2
- ZNF365 | c.7C>A p.Q3K | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZNF621 | c.626G>A p.C209Y | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF804B | c.1262G>A p.S421N | Missense Mutation (SNP) | VAF 21/301 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.009); called by muse, mutect2
- ADAMTS5 | c.1755A>G p.G585= | Silent (SNP) | VAF 9/155 reads (6%) | called by muse, mutect2
- AMELX | c.559C>A p.R187= | Silent (SNP) | VAF 59/224 reads (26%) | catalogued as COSV61631397; called by muse, mutect2, varscan2
- APMAP | c.231C>G p.L77= | Silent (SNP) | VAF 16/290 reads (6%) | called by muse, mutect2
- BRINP3 | c.1269G>T p.T423= | Silent (SNP) | VAF 23/205 reads (11%) | catalogued as COSV66530078, COSV66539699; called by muse, mutect2
- CABP5 | c.421C>A p.R141= | Silent (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- CBLN2 | c.375C>A p.G125= | Silent (SNP) | VAF 23/150 reads (15%) | called by muse, mutect2, varscan2
- CHRM3 | c.480G>T p.L160= | Silent (SNP) | VAF 28/219 reads (13%) | called by muse, mutect2, varscan2
- CLPB | c.1800C>G p.L600= | Silent (SNP) | VAF 21/161 reads (13%) | catalogued as COSV99578478; called by muse, mutect2, varscan2
- DCHS2 | c.1614C>T p.L538= | Silent (SNP) | VAF 13/153 reads (8%) | catalogued as rs1475371386; called by muse, mutect2
- DIAPH1 | c.3516A>G p.A1172= | Silent (SNP) | VAF 53/768 reads (7%) | called by muse, mutect2
- FAM47C | c.471G>A p.R157= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as rs1556331552; called by muse, mutect2
- FCGBP | c.1428C>T p.G476= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs1316432878; called by muse, mutect2, varscan2
- FLNA | c.2646C>G p.L882= | Silent (SNP) | VAF 24/89 reads (27%) | called by muse, mutect2, varscan2
- GFI1B | c.330C>T p.T110= | Silent (SNP) | VAF 32/241 reads (13%) | catalogued as COSV59747067; called by muse, mutect2, varscan2
- GOLGA1 | c.828C>T p.S276= | Silent (SNP) | VAF 27/262 reads (10%) | catalogued as rs866145317; called by muse, mutect2, varscan2
- GSTM3 | c.564C>T p.F188= | Silent (SNP) | VAF 12/340 reads (4%) | called by muse, mutect2
- ICE1 | c.4692A>G p.S1564= | Silent (SNP) | VAF 13/186 reads (7%) | called by muse, mutect2
- IGKV1-27 | c.42G>T p.L14= | Silent (SNP) | VAF 21/215 reads (10%) | catalogued as rs761663481; called by muse, mutect2
- IGLV1-47 | c.273C>A p.A91= | Silent (SNP) | VAF 12/177 reads (7%) | called by muse, mutect2
- LAMA2 | c.2289G>A p.A763= | Silent (SNP) | VAF 26/402 reads (6%) | catalogued as rs754496465, COSV70354800; ClinVar: uncertain significance; called by muse, mutect2
- MCC | c.333A>C p.S111= | Silent (SNP) | VAF 9/180 reads (5%) | catalogued as rs1331725047; called by muse, mutect2
- MDN1 | c.7830G>A p.L2610= | Silent (SNP) | VAF 24/334 reads (7%) | called by muse, mutect2
- MPP6 | c.27G>T p.T9= | Silent (SNP) | VAF 34/256 reads (13%) | catalogued as COSV56037657; called by muse, mutect2, varscan2
- MYO15A | c.2136G>A p.P712= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- NFYA | c.693C>T p.V231= | Silent (SNP) | VAF 16/184 reads (9%) | called by muse, mutect2
- NWD2 | c.4437C>T p.T1479= | Silent (SNP) | VAF 15/304 reads (5%) | called by muse, mutect2
- OR4D10 | c.120G>T p.L40= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV73260234; called by muse, mutect2, varscan2
- PCDH11X | c.216G>T p.V72= | Silent (SNP) | VAF 68/291 reads (23%) | called by muse, mutect2, varscan2
- PDE6B | c.174G>A p.A58= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as rs1183580191; called by muse, mutect2, varscan2
- PGR | c.2238C>T p.D746= | Silent (SNP) | VAF 35/326 reads (11%) | catalogued as COSV99678234; called by muse, mutect2, varscan2
- RTL1 | c.3523C>A p.R1175= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1181083648, COSV66017272; called by muse, mutect2
- RWDD2A | c.99T>C p.D33= | Silent (SNP) | VAF 32/494 reads (6%) | called by muse, mutect2
- RYR2 | c.8001T>A p.P2667= | Silent (SNP) | VAF 14/270 reads (5%) | called by muse, mutect2
- RYR3 | c.3279G>T p.V1093= | Silent (SNP) | VAF 20/475 reads (4%) | called by muse, mutect2
- SGSM1 | c.3414G>A p.V1138= (on ENST00000400359 / NM_001039948.4; = p.V1077= on NM_133454.3) | Silent (SNP) | VAF 13/257 reads (5%) | catalogued as rs1443443803; called by muse, mutect2
- SRCAP | c.6267G>T p.L2089= | Silent (SNP) | VAF 15/200 reads (8%) | called by muse, mutect2
- SYCE1L | c.36G>T p.A12= | Silent (SNP) | VAF 19/166 reads (11%) | catalogued as rs1342674159, COSV99941794; called by muse, mutect2, varscan2
- SYNGAP1 | c.1278C>T p.N426= | Silent (SNP) | VAF 38/438 reads (9%) | called by muse, mutect2
- SYNPO | c.1887G>A p.E629= (on ENST00000394243 / NM_001166208.2; = p.E385= on NM_007286.6) | Silent (SNP) | VAF 8/172 reads (5%) | called by muse, mutect2
- TAS2R31 | c.190T>C p.L64= | Silent (SNP) | VAF 17/323 reads (5%) | catalogued as rs371468130; called by muse, mutect2
- TMEM63C | c.1626C>T p.G542= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as rs758029187, COSV53602332; called by muse, mutect2, varscan2
- TRIM48 | c.414G>T p.R138= | Silent (SNP) | VAF 39/374 reads (10%) | catalogued as rs1348653598; called by muse, mutect2, varscan2
- USH2A | c.14631C>A p.P4877= | Silent (SNP) | VAF 28/457 reads (6%) | called by muse, mutect2
- VWA3A | c.3102C>T p.G1034= | Silent (SNP) | VAF 4/40 reads (10%) | called by mutect2, varscan2
- WDR55 | c.513C>A p.I171= | Silent (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2, varscan2
- XAF1 | c.324G>A p.R108= | Silent (SNP) | VAF 17/204 reads (8%) | called by muse, mutect2
- ZAR1L | c.219C>T p.S73= | Silent (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- ZNF26 | c.231C>T p.A77= | Silent (SNP) | VAF 7/70 reads (10%) | called by muse, varscan2
- ZP2 | c.438C>A p.T146= | Silent (SNP) | VAF 26/232 reads (11%) | called by muse, mutect2, varscan2
- ACSL4 | c.-346T>A | 5'UTR (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.4284+1697C>T | Intron (SNP) | VAF 24/446 reads (5%) | catalogued as rs1267707515, COSV67141418; called by muse, mutect2
- AL353804.7 | chrX:73847376 G>A | 5'Flank (SNP) | VAF 23/114 reads (20%) | catalogued as rs1483591364; called by muse, mutect2, varscan2
- ANKRD20A8P | n.1055T>C | RNA (SNP) | VAF 47/570 reads (8%) | catalogued as COSV71423553; called by muse, mutect2
- AP000769.3 | chr11:65501928 G>C | 5'Flank (SNP) | VAF 20/298 reads (7%) | called by muse, mutect2
- ARID3B | c.*2162G>T | 3'UTR (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- C4A | chr6:32005952 C>T | 3'Flank (SNP) | VAF 18/147 reads (12%) | called by muse, mutect2, varscan2
- CNNM1 | c.2176+3657G>T | Intron (SNP) | VAF 13/232 reads (6%) | called by muse, mutect2
- CNTRL | c.3963+29C>A | Intron (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- COL6A5 | c.*81A>T | 3'UTR (SNP) | VAF 36/223 reads (16%) | catalogued as COSV55217489; called by muse, mutect2, varscan2
- DAP | c.*209T>A | 3'UTR (SNP) | VAF 35/472 reads (7%) | called by muse, mutect2
- DNAI2 | c.*25A>G | 3'UTR (SNP) | VAF 48/204 reads (24%) | catalogued as rs903587964; called by muse, mutect2, varscan2
- EXT1 | c.*40G>T | 3'UTR (SNP) | VAF 24/154 reads (16%) | called by muse, mutect2, varscan2
- GABRA1 | c.-16+514C>A | Intron (SNP) | VAF 16/176 reads (9%) | called by muse, mutect2
- GTF2H2B | n.276-352G>A | Intron (SNP) | VAF 15/162 reads (9%) | called by muse, mutect2, varscan2
- GUCY2EP | n.17G>T | RNA (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- HGF | c.482+31C>G | Intron (SNP) | VAF 68/354 reads (19%) | called by muse, mutect2, varscan2
- INTS14 | c.-97T>A | 5'UTR (SNP) | VAF 16/174 reads (9%) | called by muse, mutect2
- KIF21B | chr1:200973586 G>T | 3'Flank (SNP) | VAF 8/78 reads (10%) | called by muse, varscan2
- LINC00305 | n.765-10C>A | Intron (SNP) | VAF 26/161 reads (16%) | called by muse, mutect2, varscan2
- NOL4L-DT | n.529del | RNA (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel, varscan2
- OR2W5 | n.572C>A | RNA (SNP) | VAF 27/177 reads (15%) | called by muse, mutect2, varscan2
- POLR3B | c.3273-1652C>A | Intron (SNP) | VAF 35/316 reads (11%) | called by muse, mutect2, varscan2
- RCC1 | c.-228-239C>T | Intron (SNP) | VAF 17/208 reads (8%) | catalogued as COSV100775668; called by muse, mutect2
- RGL2 | c.241-103C>G | Intron (SNP) | VAF 24/304 reads (8%) | called by muse, mutect2
- RXFP1 | c.287-24C>A | Intron (SNP) | VAF 35/266 reads (13%) | called by muse, mutect2, varscan2
- SNAI2 | c.625+23G>T | Intron (SNP) | VAF 17/370 reads (5%) | catalogued as rs1451480696; called by muse, mutect2
- SNX17 | c.*761C>G | 3'UTR (SNP) | VAF 16/214 reads (7%) | called by muse, mutect2
- UBTFL2 | n.792C>T | RNA (SNP) | VAF 22/398 reads (6%) | catalogued as rs377504869; called by muse, mutect2
